Somatic mutation profile of tumor specimen TCGA-DJ-A4UL-01A (aliquot TCGA-DJ-A4UL-01A-11D-A257-08) from TCGA case TCGA-DJ-A4UL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 68.3 years (24,939 days).
Specimen TCGA-DJ-A4UL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 101dc446-59a5-496e-8d95-4e4c966be7b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4UL-10A (Blood Derived Normal), aliquot TCGA-DJ-A4UL-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65f9a065-6bab-4c52-a7c4-c41197a34318

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAH9 | c.9637G>A p.V3213I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV52333669; called by muse, mutect2, varscan2
- GLIS3 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60923868; called by muse, mutect2, varscan2
- GOLGA3 | c.4302G>C p.Q1434H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52625300; called by muse, mutect2, varscan2
- GPR89A | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1196975121, COSV100572378; called by muse, mutect2, varscan2
- OR4A47 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs148277853; called by muse, mutect2, varscan2
- BHLHE40 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DRD4 | c.1242C>T p.A414= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs772240299, COSV51561630; called by muse, mutect2, varscan2
- EVPL | c.2190C>G p.R730= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV56907276; called by muse, mutect2, varscan2
- GIMAP1 | c.375C>T p.T125= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs750429019, COSV56187053; called by muse, mutect2, varscan2
- MCCD1 | c.150G>A p.G50= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV66018577; called by muse, mutect2, varscan2
